Somatic mutation profile of tumor specimen C3L-04853-01 (aliquot CPT0248590007) from CPTAC case C3L-04853, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 85.5 years (31,222 days).
Specimen C3L-04853-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fca9cdb-ba24-4eab-a51c-9173c58fb265.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04853-31 (Blood Derived Normal), aliquot CPT0248630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e0cf4f0-378e-4f67-9dd1-3e778412ab23

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 26/270 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.783-1G>A p.X261_splice | Splice Site (SNP) | VAF 51/453 reads (11%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6157G>T p.V2053L (on ENST00000614293; = p.V2023L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV55806269; called by muse, mutect2, varscan2
- AC131160.1 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs749724696; called by muse, mutect2, varscan2
- ADCY2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.106); catalogued as rs576240306, COSV100601879, COSV57864504; called by muse, mutect2
- AVL9 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1282573346, COSV59465213; called by muse, mutect2
- BRSK1 | c.1860C>G p.I620M | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV58668965; called by muse, mutect2
- C16orf96 | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs975896413, COSV71471671; called by muse, mutect2, varscan2
- FRY | c.7918C>T p.R2640W | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.339); catalogued as rs1169375154; called by muse, mutect2
- HNRNPR | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs763561835; called by muse, mutect2, varscan2
- KCNA7 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.326); catalogued as rs765895551; called by muse, mutect2, varscan2
- MAGEA4 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs755062941, COSV52340702; called by muse, mutect2
- MGAM | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs782549716, COSV72073695; called by muse, mutect2
- MUC4 | c.13765C>T p.R4589* (on ENST00000463781 / NM_018406.7; = p.R353* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | catalogued as rs771701130, COSV57801324; called by muse, mutect2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, mutect2
- MYPN | c.2574G>T p.Q858H | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.556); catalogued as COSV62732852; called by muse, mutect2
- OR8A1 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs753980426, COSV99421034; called by muse, mutect2, varscan2
- PTK2B | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs369608545; called by muse, mutect2
- RBM10 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 29/431 reads (7%) | catalogued as COSV100237880; called by muse, mutect2
- RBMXL3 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.094); catalogued as rs1556556197, COSV57759976; called by muse, mutect2
- SEMA5A | c.2603G>A p.C868Y | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66807066; called by muse, mutect2
- TENM4 | c.7722G>C p.L2574F | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV53653018; called by muse, mutect2
- TMEM63C | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs756710566, COSV53604461; called by muse, mutect2, varscan2
- TRPM5 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs770117161; called by muse, mutect2, varscan2
- TUB | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs144469939; called by muse, mutect2
- BDP1 | c.7620G>T p.K2540N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- GPR26 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- H1-8 | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- KCTD16 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KRT20 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NXF3 | c.1581A>T p.K527N | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2
- STARD9 | c.3239T>A p.M1080K | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ARR3 | c.276G>C p.G92= | Silent (SNP) | VAF 18/334 reads (5%) | catalogued as COSV57204990; called by muse, mutect2
- BRSK1 | c.1971C>T p.F657= | Silent (SNP) | VAF 46/478 reads (10%) | catalogued as COSV58670721; called by muse, mutect2
- CLDN17 | c.69C>T p.A23= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2
- DPH2 | c.954C>A p.A318= | Silent (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- KCNN1 | c.657C>G p.P219= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- NEUROG1 | c.330G>A p.A110= | Silent (SNP) | VAF 43/348 reads (12%) | catalogued as COSV59082746; called by muse, mutect2, varscan2
- PDE8B | c.1272A>G p.S424= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as rs1253489761; called by muse, mutect2
- PIK3R5 | c.2154C>T p.I718= | Silent (SNP) | VAF 30/243 reads (12%) | catalogued as rs148443913, COSV52650541; called by muse, mutect2, varscan2
- PTGFR | c.144C>A p.I48= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as COSV66114817; called by muse, mutect2
- RNF213 | c.2715G>T p.G905= | Silent (SNP) | VAF 27/528 reads (5%) | catalogued as rs373595025; called by muse, mutect2
- SH3RF2 | c.1182T>C p.H394= | Silent (SNP) | VAF 22/413 reads (5%) | catalogued as rs750545470; called by muse, mutect2
- SLC22A8 | c.1383G>A p.P461= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs765180492; called by muse, mutect2
- STRA8 | c.750C>A p.A250= (on ENST00000275764; = p.A228= on NM_182489.2) | Silent (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- TEKT4 | c.201C>T p.H67= | Silent (SNP) | VAF 20/346 reads (6%) | catalogued as rs199545713; called by muse, mutect2
- SDF4 | c.557-48G>A | Intron (SNP) | VAF 31/260 reads (12%) | catalogued as rs376779621; called by muse, mutect2, varscan2
